Gene-level copy-number profile of tumor specimen ALCH-ABD5-TTP1-A from ALCHEMIST case ALCH-ABD5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.9 years (27,000 days).
Specimen ALCH-ABD5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4958a9b7-e9d2-4eb5-a810-b8ee980b505e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABD5-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/5a97d665-06fd-4512-bb24-ebaef17b8880

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 66; copy number 2: 56,430; copy number 3: 1,717; copy number 4: 76; copy number 6: 87; copy number 7: 4; copy number 8: 19.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 110 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:148,808,181–149,048,286, 1 gene, copy number 7 (within-gene range 3–7): PDE4DIP.
- chr1:148,939,739–149,026,269, 3 genes, copy number 7: RNU2-38P, AC239802.1, AC239802.2.
- chr1:159,289,714–159,782,543, 19 genes, copy number 8: FCER1A, OR10J3, AL513323.1, OR10J7P, OR10J8P, OR10J9P, OR10J4, OR10J1, LINC02819, OR10J5, AL606752.1, OR10AE1P, APCS, OR10J6P, AL445528.2, CRPP1, CRP, AL445528.1, DUSP23.
- chr1:160,288,594–160,343,273, 3 genes, copy number 6 (within-gene range 2–6): COPA, SUMO1P3, Y_RNA.
- chr7:53,316,149–56,538,676, 84 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 66. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
